Somatic mutation profile of tumor specimen TCGA-BR-6709-01A (aliquot TCGA-BR-6709-01A-11D-1882-08) from TCGA case TCGA-BR-6709, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 57.3 years (20,935 days).
Specimen TCGA-BR-6709-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f26a1912-6ba0-4b99-b1ff-673812d6fd0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6709-10A (Blood Derived Normal), aliquot TCGA-BR-6709-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e851195-d8b6-45c5-8cbe-13c279945a96

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 3, RNA 2, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.494); catalogued as rs747317920, COSV51485991; called by muse, mutect2, varscan2
- AUTS2 | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100719614; called by muse, mutect2
- CACNA2D4 | c.3382G>A p.A1128T | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54945198; called by muse, mutect2
- CAPRIN2 | c.1692G>C p.Q564H | Missense Mutation (SNP) | VAF 18/654 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV51833718, COSV99195715; called by muse, mutect2
- CSMD3 | c.5558C>A p.T1853N (on ENST00000297405 / NM_001363185.1; = p.T1749N on NM_052900.3) | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV52140889; called by muse, mutect2, varscan2
- CTSW | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 598/1105 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1313661277, COSV100327553; called by muse, mutect2, varscan2
- CTSW | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1220055031, COSV100327555; called by muse, varscan2
- DCC | c.1683C>G p.Y561* | Nonsense Mutation (SNP) | VAF 43/231 reads (19%) | catalogued as COSV100503250, COSV59085880; called by muse, mutect2, varscan2
- DCLK1 | c.917A>G p.K306R | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.78); catalogued as COSV99713198, COSV99713397; called by muse, mutect2, varscan2
- DEF6 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs766125119, COSV100359155, COSV99079508; called by muse, mutect2, varscan2
- EED | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99646650; called by muse, mutect2
- ERICH3 | c.2453A>G p.Q818R | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as COSV100445882, COSV58613592; called by muse, mutect2, varscan2
- HIVEP2 | c.4490G>T p.R1497L | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs757655292, COSV99175624; called by muse, mutect2, varscan2
- HSPB11 | c.112T>G p.F38V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99524106; called by muse, mutect2, varscan2
- HSPG2 | c.9710-1G>A p.X3237_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65933424; called by muse, mutect2
- PAFAH1B1 | c.665A>G p.Q222R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV101250457; called by muse, mutect2, varscan2
- POGLUT1 | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99809872; called by muse, mutect2, varscan2
- PPP1R42 | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV100221480; called by muse, mutect2
- SYT10 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746333902, COSV57338562; called by muse, mutect2
- TMEM8B | c.1000A>G p.M334V | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs748640951, COSV100941741; called by muse, mutect2
- TTN | c.51866G>C p.R17289T (on ENST00000591111; = p.R9865T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | PolyPhen probably damaging (0.996); catalogued as COSV100599100; called by muse, mutect2, varscan2
- UNC13C | c.3941T>A p.V1314E | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV99523232; called by muse, mutect2
- VPS41 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.471); catalogued as COSV100054376, COSV59647181; called by muse, mutect2, varscan2
- WWC3 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs748994685, COSV101081490; called by muse, mutect2, varscan2
- ZBBX | c.1781T>G p.L594R | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100285015, COSV56781664; called by muse, mutect2, varscan2
- ZMYM3 | c.2650C>G p.Q884E | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100078401; called by muse, mutect2, varscan2
- ZNF559 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100416764; called by muse, mutect2
- MAN1A2 | c.1317_1318dup p.G440Vfs*32 | Frame Shift Ins (INS) | VAF 16/132 reads (12%) | called by mutect2, pindel, varscan2
- CACNA1C | c.711G>A p.R237= | Silent (SNP) | VAF 124/1696 reads (7%) | catalogued as COSV100222465; called by muse, mutect2
- CTSW | c.291G>A p.E97= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as rs1449002178, COSV57173206; called by muse, varscan2
- GNAI2 | c.675C>T p.C225= | Silent (SNP) | VAF 8/145 reads (6%) | catalogued as rs141703681; called by muse, mutect2
- MIA2 | c.2169T>C p.P723= | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as COSV54502315; called by muse, mutect2, varscan2
- OVCH1 | c.2421C>A p.I807= | Silent (SNP) | VAF 32/956 reads (3%) | catalogued as COSV100549254; called by muse, mutect2
- PTCH2 | c.2250C>T p.A750= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100942285; called by muse, mutect2, varscan2
- SKP1 | c.141A>G p.L47= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs756453088, COSV100104659; called by muse, mutect2, varscan2
- DCHS2 | n.6415C>T | RNA (SNP) | VAF 11/120 reads (9%) | catalogued as COSV100602701; called by muse, mutect2
- KAT6A | c.1483-1831G>T | Intron (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- SSPOP | n.5756G>A | RNA (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100023036; called by muse, mutect2, varscan2
